Somatic mutation profile of tumor specimen TCGA-QS-A744-01A (aliquot TCGA-QS-A744-01A-11D-A34Q-09) from TCGA case TCGA-QS-A744, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Isthmus uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 86.3 years (31,520 days).
Specimen TCGA-QS-A744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ea213ff-6c05-4fdc-ba32-66f55d44345b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QS-A744-10B (Blood Derived Normal), aliquot TCGA-QS-A744-10B-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21a7ed80-0c25-42ca-b33b-901145d97fb4

The open-access MAF lists 70 somatic variants for this specimen: 54 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Nonsense Mutation 4, In Frame Del 3, Splice Region 2, Frame Shift Del 1, 5'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 34/83 reads (41%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.11950C>A p.L3984I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447281; called by muse, mutect2, varscan2
- AKAP11 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99214443; called by muse, mutect2, varscan2
- ANPEP | c.2358C>T p.N786= | Splice Region (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100263618; called by muse, mutect2, varscan2
- ARHGAP35 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101351872, COSV68329702; called by muse, mutect2, varscan2
- ARID1A | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV100251003; called by muse, mutect2, varscan2
- BCLAF3 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs748091360, COSV100811195; called by muse, mutect2, varscan2
- BRWD3 | c.3808-1G>A p.X1270_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV64749123; called by muse, mutect2, varscan2
- CACNA1E | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.289); catalogued as rs1227533595, COSV100705749; called by muse, mutect2, varscan2
- CD93 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs139005135; called by muse, mutect2, varscan2
- CST7 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.399); catalogued as rs1224078020, COSV99469178; called by muse, mutect2, varscan2
- DICER1 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58615244, COSV58615703, COSV58615881; called by muse, mutect2, varscan2
- DICER1 | c.2224T>A p.S742T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as COSV100602647; called by muse, mutect2, varscan2
- EPHA6 | c.1930G>A p.V644M (on ENST00000389672 / NM_001080448.3; = p.V36M on NM_173655.4) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV101065543, COSV67592977; called by muse, mutect2, varscan2
- EPPK1 | c.4111G>A p.G1371R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs376905444; called by muse, mutect2, varscan2
- FOXD4L4 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1452933158; called by muse, mutect2, varscan2
- GRM7 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559306156, COSV63159229, COSV63162440; called by muse, mutect2, varscan2
- HUWE1 | c.11349A>C p.Q3783H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99474758; called by muse, mutect2, varscan2
- IGLV3-32 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs773491244; called by muse, mutect2, varscan2
- ISM1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs376403685, COSV52609464; called by muse, mutect2, varscan2
- KDM6B | c.2119C>A p.R707S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV54683682, COSV99642486; called by muse, mutect2, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2
- LRP1 | c.4436C>T p.S1479L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1025839584, COSV54510193; called by muse, mutect2, varscan2
- MARS1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs755272942, COSV56252548; called by muse, mutect2, varscan2
- NBEA | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV59769661, COSV59834850; called by muse, mutect2, varscan2
- NBEA | c.3677C>T p.A1226V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.028); catalogued as rs1348731685, COSV59779612; called by muse, mutect2, varscan2
- NES | c.694C>G p.R232G | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100958028; called by muse, mutect2, varscan2
- NID2 | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99357413; called by muse, mutect2, varscan2
- NOP14 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.56); catalogued as rs1226895779, COSV100055115; called by muse, mutect2, varscan2
- OBSCN | c.4525G>A p.A1509T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs373224911; called by muse, mutect2, varscan2
- PCBP4 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142190169; called by muse, mutect2, varscan2
- POFUT1 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003390; called by muse, mutect2, varscan2
- PRXL2A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV100939847; called by muse, mutect2, varscan2
- PTEN | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 92/134 reads (69%) | catalogued as rs1554825186, COSV64291904, COSV64303316; called by muse, varscan2
- RLIM | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs751112634, COSV60325920; called by muse, mutect2, varscan2
- SLC5A7 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs748755332, COSV50891064; called by muse, mutect2, varscan2
- SMTN | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs538229101, COSV60779078; called by muse, mutect2, varscan2
- SOX13 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99690083; called by muse, varscan2
- SOX17 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99810886; called by muse, mutect2
- SPEG | c.7729C>T p.R2577C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs745512518, COSV100405880; called by muse, mutect2, varscan2
- SPEG | c.8566C>T p.R2856W | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs749419099, COSV100405881; called by muse, mutect2, varscan2
- TTPA | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.524); catalogued as COSV99478659; called by muse, mutect2, varscan2
- USP10 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs776823223, COSV99551922; called by muse, mutect2, varscan2
- VPS13D | c.6272C>T p.T2091M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs777900758, COSV99170005; called by muse, mutect2, varscan2
- CIRBP | c.502+4_502+16dup | Splice Region (INS) | VAF 12/48 reads (25%) | called by mutect2, varscan2
- CLCN4 | c.1882_1884del p.E628del | In Frame Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- CREBBP | c.4477_4479del p.I1493del | In Frame Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- FCGBP | c.9425G>C p.R3142P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGB6 | c.1988C>A p.S663* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PTEN | c.662del p.K221Rfs*2 | Frame Shift Del (DEL) | VAF 27/132 reads (20%) | called by pindel, varscan2
- PTTG2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.931); called by muse, mutect2
- BCS1L | c.42C>T p.P14= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99828962, COSV99829261; called by muse, mutect2, varscan2
- CERK | c.798G>A p.S266= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs751738148, COSV53452910; called by muse, mutect2, varscan2
- GLI2 | c.3186C>T p.D1062= (on ENST00000361492 / NM_001374353.1; = p.D1079= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs769533860, COSV58049393; ClinVar: uncertain significance; called by muse, varscan2
- KRTAP19-7 | c.54C>T p.F18= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs572700402, COSV58366022, COSV58366262; called by muse, mutect2, varscan2
- NRG1 | c.705G>A p.A235= (on ENST00000405005 / NM_013964.5; = p.A240= on NM_013956.5) | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs770570976, COSV99828232, COSV99828243; called by muse, mutect2, varscan2
- OR10J3 | c.252T>C p.S84= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100171927; called by muse, mutect2, varscan2
- OR5T1 | c.573T>C p.C191= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100479270; called by muse, mutect2, varscan2
- PTPN11 | c.402T>C p.S134= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100692906; called by muse, mutect2, varscan2
- RPTOR | c.1617C>T p.L539= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs775568563, COSV100157553; called by muse, mutect2, varscan2
- SCN4A | c.2097G>A p.A699= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as rs765222494, COSV71128056; called by muse, mutect2, varscan2
- SRCIN1 | c.2493G>A p.A831= (on ENST00000621492; = p.A797= on NM_025248.3) | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs1006950455; called by muse, mutect2, varscan2
- SUCLA2 | c.438A>C p.G146= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101074998; called by muse, mutect2, varscan2
- TTN | c.21990C>T p.S7330= (on ENST00000591111; = p.S6403= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs544355195, COSV59888695; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNRF4 | c.444G>A p.P148= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs867828770, COSV55773401; called by muse, mutect2, varscan2
- DOT1L | c.4606+1105C>T | Intron (SNP) | VAF 3/37 reads (8%) | catalogued as rs1432818709; called by muse, mutect2
- SLC3A2 | chr11:62855629 G>T | 5'Flank (SNP) | VAF 13/27 reads (48%) | catalogued as rs771051574; called by muse, mutect2
